Gene-level copy-number profile of tumor specimen TCGA-A2-A3XX-01A from TCGA case TCGA-A2-A3XX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 49.2 years (17,981 days).
Specimen TCGA-A2-A3XX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1a12cd14-3f98-41bd-b89f-c0fb2848f8d5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A3XX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/25a50788-41d8-43ed-a870-710ae17f4a78

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 797; copy number 3: 23,877; copy number 4: 19,510; copy number 5: 5,139; copy number 6: 5,046; copy number 7: 1,054; copy number 9: 3; copy number 10: 2,604; copy number 12: 95; copy number 14: 648; copy number 15: 841; copy number 16: 19; copy number 17: 34; copy number 18: 1; copy number 20: 98; copy number 24: 24; copy number 60: 8; copy number 61: 10; copy number 64: 1; copy number 71: 6; copy number 74: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A3XX-01A-21D-A238-01): tumor purity 0.55, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,450 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 10 (broad region; genes not listed).
- chr5:58,198–15,496,353, 276 genes, copy number 7 (broad region; genes not listed).
- chr5:15,602,189–15,619,109, 1 gene, copy number 7: CTD-2350J17.1.
- chr6:23,124,981–44,307,506, 938 genes, copy number 7–74 (within-gene range 6–74) (broad region; genes not listed).
- chr6:44,278,734–44,297,698, 1 gene, copy number 20: TCTE1.
- chr8:40,900,016–50,796,692, 156 genes, copy number 14–24 (within-gene range 6–24) (broad region; genes not listed).
- chr8:55,067,585–72,950,445, 265 genes, copy number 15 (broad region; genes not listed).
- chr8:73,879,046–145,066,685, 1,111 genes, copy number 14–16 (broad region; genes not listed).
- chr16:70,802,084–71,230,722, 1 gene, copy number 9 (within-gene range 5–9): HYDIN.
- chr16:71,080,866–71,114,000, 2 genes, copy number 9: AC138625.2, AC138625.1.
- chr19:38,836,388–40,426,702, 95 genes, copy number 12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
